Somatic mutation profile of tumor specimen TCGA-66-2765-01A (aliquot TCGA-66-2765-01A-01D-1522-08) from TCGA case TCGA-66-2765, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.2 years (23,465 days).
Specimen TCGA-66-2765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6046213b-3ae2-4f66-9b52-69a8fc6dc1f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2765-11A (Solid Tissue Normal), aliquot TCGA-66-2765-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30ab18be-f46a-458f-809e-9c345d6512f5

The open-access MAF lists 99 somatic variants for this specimen: 81 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 15, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, RNA 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QB | c.394del p.L132Cfs*12 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as rs1064797108; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.993+2T>A p.X331_splice | Splice Site (SNP) | VAF 65/143 reads (45%) | hotspot (GDC flag); catalogued as COSV52703680, COSV52798259, COSV52814192; called by muse, mutect2, varscan2
- AASS | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV62788792; called by muse, mutect2, varscan2
- ABCB5 | c.2119C>T p.P707S (on ENST00000404938 / NM_001163941.2; = p.P262S on NM_178559.6) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51702889; called by muse, varscan2
- ABCC3 | c.4312C>G p.R1438G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53317058; called by muse, mutect2, varscan2
- ACO1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs758468204, COSV59376576; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1016206418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY7 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV54264310; called by muse, mutect2, varscan2
- ADGRF4 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51949439; called by muse, mutect2, varscan2
- ANGPTL5 | c.699A>G p.I233M | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV57531740; called by muse, mutect2, varscan2
- ARMH4 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 89/472 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs572182783, COSV50761538; called by muse, mutect2, varscan2
- CACNA1G | c.5324C>A p.P1775H | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1238153214, COSV61720057, COSV61729672; called by muse, mutect2, varscan2
- CD2BP2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as rs772753316, COSV59768078; called by muse, mutect2, varscan2
- CILP2 | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.142); catalogued as COSV52272477; called by muse, mutect2, varscan2
- CNTN5 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV54279691; called by muse, mutect2, varscan2
- COL4A6 | c.612A>T p.Q204H | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV57858990, COSV57865988; called by muse, mutect2, varscan2
- DDX27 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV65628940; called by muse, mutect2, varscan2
- DUOX2 | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs551638726, COSV66530519; called by muse, mutect2, varscan2
- DUSP12 | c.959A>G p.H320R | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs544973471, COSV63411083; called by muse, mutect2, varscan2
- EFR3A | c.1989C>A p.N663K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV54453091; called by muse, mutect2, varscan2
- EIF2B2 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV56719793; called by muse, mutect2, varscan2
- FLG | c.3989G>A p.G1330D | Missense Mutation (SNP) | VAF 115/531 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs752028692, COSV64236240; called by muse, varscan2
- FSTL5 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as COSV60180843; called by muse, mutect2, varscan2
- FUZ | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV58240781; called by muse, mutect2, varscan2
- GPC2 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as COSV52783817, COSV52786105; called by muse, mutect2, varscan2
- GPR61 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68177301; called by muse, mutect2, varscan2
- H4C2 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV55137492, COSV55141384; called by muse, mutect2, varscan2
- JPH2 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV65901765; called by muse, mutect2, varscan2
- KCNJ3 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV54531208; called by muse, mutect2, varscan2
- KMT2C | c.5803C>T p.P1935S | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV51286074; called by muse, mutect2, varscan2
- KMT2D | c.10078C>T p.Q3360* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV56409739; called by muse, mutect2, varscan2
- KMT2D | c.5051G>C p.S1684T | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.212); catalogued as COSV56409762; called by muse, mutect2, varscan2
- LCA5 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1312880, COSV63970484; called by muse, mutect2, varscan2
- LCT | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs945583065, COSV51543950; called by muse, mutect2, varscan2
- LRP2 | c.4828A>G p.R1610G | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV55540434; called by muse, mutect2, varscan2
- MBD5 | c.4099C>G p.P1367A | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1419918297, COSV68695735; called by muse, mutect2, varscan2
- MPDZ | c.2618A>G p.Y873C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs753255849, COSV59935429; called by muse, mutect2, varscan2
- MTOR | c.204C>G p.N68K | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63868308; called by muse, mutect2, varscan2
- NECTIN4 | c.792A>C p.E264D | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV63511920; called by muse, mutect2, varscan2
- NES | c.4130C>A p.P1377H | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100957903, COSV63960338; called by muse, mutect2, varscan2
- NLRP3 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs199856287, CM1413286, COSV60219661, COSV60221397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPBWR2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs764251247, COSV63899773; called by muse, mutect2, varscan2
- NT5C3A | c.308-1G>C p.X103_splice (on ENST00000610140 / NM_001374335.1; = p.X69_splice on NM_016489.13) | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV54236749, COSV99640883; called by muse, mutect2, varscan2
- OR4C6 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV58602459; called by muse, mutect2, varscan2
- OR4N2 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV60049916; called by muse, mutect2
- OR52J3 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1247837063, COSV66746307, COSV66746315; called by muse, mutect2, varscan2
- PADI6 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61883699; called by muse, mutect2, varscan2
- PCSK9 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs773699134, COSV56160516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3AP1 | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 94/434 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV59530241; called by muse, mutect2, varscan2
- PIK3C2A | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV56400275; called by muse, mutect2
- PIK3C2A | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 20/551 reads (4%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV56400281; called by muse, mutect2
- PPEF1 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62995116; called by muse, mutect2, varscan2
- PRSS55 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as COSV60807655; called by muse, mutect2, varscan2
- RORC | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.028); catalogued as COSV59091182; called by muse, mutect2, varscan2
- RPP40 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1229764270, COSV60291225; called by muse, mutect2, varscan2
- SALL2 | c.2642C>G p.P881R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV58102002; called by muse, mutect2, varscan2
- SDC2 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56225729; called by muse, mutect2, varscan2
- SERPINB2 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55090994; called by muse, mutect2, varscan2
- SHROOM4 | c.4000G>C p.G1334R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56784034; called by muse, mutect2, varscan2
- SLC22A25 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV100124127, COSV60594394; called by muse, mutect2, varscan2
- SLC6A5 | c.2137T>A p.W713R | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54223468; called by muse, mutect2, varscan2
- SMPD4 | c.1132G>T p.A378S (on ENST00000409031 / NM_017951.4; = p.A349S on NM_017751.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.853); catalogued as COSV60078482; called by muse, mutect2, varscan2
- SULF2 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.378); catalogued as COSV63413823; called by muse, mutect2, varscan2
- TRAPPC5 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV58039412, COSV58040334; called by muse, mutect2, varscan2
- TRHDE | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV53832238; called by muse, mutect2, varscan2
- TTN | c.46732C>A p.Q15578K (on ENST00000591111; = p.Q8154K on NM_003319.4) | Missense Mutation (SNP) | VAF 176/696 reads (25%) | PolyPhen benign (0.006); catalogued as COSV59881276; called by muse, mutect2, varscan2
- UBE2E2 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV59965369; called by muse, mutect2, varscan2
- UGT1A8 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV65073161; called by muse, mutect2, varscan2
- UTP20 | c.2134C>G p.P712A | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV55371896; called by muse, mutect2, varscan2
- VN1R2 | c.778T>A p.S260T | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV59037105; called by muse, mutect2, varscan2
- YAP1 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 327/454 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV56771743; called by muse, mutect2, varscan2
- ZBTB11 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 58/494 reads (12%) | catalogued as rs1360071778, COSV57243924; called by muse, mutect2, varscan2
- ZNF286A | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as COSV67845135; called by muse, mutect2, varscan2
- ZNF33A | c.607G>C p.E203Q (on ENST00000458705 / NM_006974.3; = p.E204Q on NM_006954.2) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV56722967, COSV56724048; called by muse, mutect2, varscan2
- ZNF747 | c.485A>G p.Q162R | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs142751951; called by muse, mutect2, varscan2
- ZNF75A | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1032363826, COSV73039558; called by muse, mutect2, varscan2
- DNAH10 | c.7227del p.S2410Lfs*12 (on ENST00000409039; = p.S2349Lfs*12 on NM_207437.3) | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel*, varscan2
- ERCC6L2 | c.4510G>T p.E1504* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- IGLV3-16 | c.318_319insA p.L107Tfs*? | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- OTUB1 | c.604_605delinsT p.E202Cfs*? (on ENST00000428192; = p.E202Cfs*185 on NM_017670.2) | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | called by pindel, varscan2*
- SDK1 | c.4265_4266delinsT p.P1422Lfs*13 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | called by pindel, varscan2*
- ABHD8 | c.687G>C p.A229= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV53112521, COSV53112543; called by muse, mutect2, varscan2
- ACMSD | c.148C>A p.R50= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV51605467, COSV51606661; called by muse, mutect2, varscan2
- CDKL3 | c.897G>A p.L299= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54739522; called by muse, mutect2, varscan2
- COL4A2 | c.3402G>C p.G1134= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV64624728; called by muse, mutect2
- DIDO1 | c.4707G>A p.E1569= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV56613483; called by muse, mutect2, varscan2
- EIF3A | c.2973C>T p.N991= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as COSV64960463; called by muse, mutect2, varscan2
- ELN | c.630C>G p.A210= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV52706869; called by muse, mutect2, varscan2
- FAM47A | c.1356T>C p.T452= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV60493912; called by muse, mutect2
- MYH7B | c.2808C>T p.A936= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1022093378, COSV53416456; called by muse, mutect2, varscan2
- RFC5 | c.717C>A p.T239= | Silent (SNP) | VAF 74/262 reads (28%) | catalogued as COSV57476846, COSV99970016; called by muse, mutect2, varscan2
- SNAP25 | c.513C>T p.I171= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs372122045; called by muse, mutect2, varscan2
- SPATA31D1 | c.696G>A p.K232= | Silent (SNP) | VAF 89/358 reads (25%) | catalogued as COSV61192674; called by muse, mutect2, varscan2
- SPATA31E1 | c.15C>T p.V5= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV57789467; called by muse, mutect2, varscan2
- USP24 | c.7146T>C p.H2382= | Silent (SNP) | VAF 58/240 reads (24%) | catalogued as COSV53761612; called by muse, mutect2, varscan2
- ZNF395 | c.1173G>C p.G391= | Silent (SNP) | VAF 60/225 reads (27%) | catalogued as COSV60427712; called by muse, mutect2, varscan2
- KSR2 | c.987-6627C>G | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100195858; called by muse, mutect2
- MIR510 | n.66G>A | RNA (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- SNORD115-4 | n.43T>G | RNA (SNP) | VAF 20/454 reads (4%) | catalogued as rs924816284; called by muse, mutect2
